ALCHEMIST case ALCH-AC3S — Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial (ALCHEMIST-ALCH)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026).
https://portal.gdc.cancer.gov/cases/2e60e2e7-8c75-4c92-ab3b-0abfbcb14bf8

Demographics
Sex at birth: female.

Diagnoses (1)
1. Adenocarcinoma, NOS: Age at diagnosis: 81.3 years (29,712 days).

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample ALCH-AC3S-NB1-A: Tissue type: Normal; Specimen type: Peripheral Whole Blood; Preservation method: Fresh.
- Sample ALCH-AC3S-TTP1-A: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
  Slide ALCH-AC3S-TTP1-A-1-0-S3: Section location: Top; Percent tumor cells: 39; Percent tumor nuclei: 65; Percent normal cells: 14; Percent necrosis: 0; Percent stromal cells: 47; Percent lymphocyte infiltration: 26; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 0.
